Gene-level copy-number profile of tumor specimen ALCH-ACX7-TTP1-A from ALCHEMIST case ALCH-ACX7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.0 years (28,838 days).
Specimen ALCH-ACX7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fe9dc96f-880a-475f-a360-21673cfd0870.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ACX7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/df9293ef-a585-4497-909d-fbf01bf8de3c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 3,132; copy number 2: 53,153; copy number 3: 2,595; copy number 4: 13; copy number 5: 1; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:32,475,051–32,478,250, 1 gene, copy number 6: ABCD1P3.
- chr21:43,461,960–43,479,534, 1 gene, copy number 5 (within-gene range 1–5): LINC00313.

Autosomal genes at a single copy (total copy number 1): 291. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
